Somatic mutation profile of tumor specimen 1105219 (aliquot 7316UP-2100-1105219) from CPTAC case C846363, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Parietal lobe; Tumor grade: G4.
Specimen 1105219: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8299f043-c330-46e5-91c1-5454420791a7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1105216 (Blood Derived Normal), aliquot 7316UP-2100-1105216; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6da934c4-caff-46a6-a195-c6a7e1316fcf

The open-access MAF lists 50 somatic variants for this specimen: 35 protein-altering or splice-affecting, 10 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 10, Nonsense Mutation 3, Intron 3, Splice Region 1, RNA 1, 5'Flank 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALG12 | c.1211G>A p.R404Q | Missense Mutation (SNP) | VAF 87/440 reads (20%) | PolyPhen probably damaging (1); catalogued as rs553349150; called by muse, mutect2, varscan2
- ANK1 | c.3427C>T p.R1143C | Missense Mutation (SNP) | VAF 80/120 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as rs764141047, COSV55886773; called by muse, mutect2, varscan2
- CABP2 | c.256G>A p.A86T | Missense Mutation (SNP) | VAF 43/80 reads (54%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs375360165, COSV53708769; called by muse, mutect2, varscan2
- CD163L1 | c.1258C>T p.R420C | Missense Mutation (SNP) | VAF 81/197 reads (41%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.823); catalogued as rs779416105, COSV58016469; called by muse, mutect2, varscan2
- CDS1 | c.642C>T p.F214= | Splice Region (SNP) | VAF 10/42 reads (24%) | catalogued as rs375840719; called by muse, mutect2, varscan2
- CHP2 | c.172G>A p.A58T | Missense Mutation (SNP) | VAF 45/232 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.435); catalogued as rs756989190, COSV55649492; called by muse, mutect2, varscan2
- DEFB114 | c.95G>A p.R32H | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.005); catalogued as rs141697166, COSV59038413; called by muse, mutect2, varscan2
- DSC2 | c.596G>A p.R199H | Missense Mutation (SNP) | VAF 65/146 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as rs374707462; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DSP | c.694C>T p.R232C | Missense Mutation (SNP) | VAF 193/499 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as rs777847026; called by muse, mutect2, varscan2
- KEL | c.537G>A p.W179* | Nonsense Mutation (SNP) | VAF 38/303 reads (13%) | catalogued as COSV100787323; called by muse, mutect2, varscan2
- LARP1B | c.175G>A p.V59I | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs150798326; called by muse, mutect2, varscan2
- LRGUK | c.1898C>T p.S633L | Missense Mutation (SNP) | VAF 21/168 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs764953610, COSV53633892; called by muse, mutect2, varscan2
- MMP3 | c.857C>T p.T286M | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.523); catalogued as rs149156238; called by muse, mutect2, varscan2
- MRGPRX4 | c.284G>A p.R95H | Missense Mutation (SNP) | VAF 89/179 reads (50%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs778327061, COSV58589894; called by muse, mutect2, varscan2
- NIPSNAP2 | c.661G>A p.G221R | Missense Mutation (SNP) | VAF 73/311 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs753851867; called by muse, mutect2, varscan2
- OR7C1 | c.613G>A p.V205I | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.021); catalogued as rs772802995, COSV50183672; called by muse, mutect2
- PFAS | c.3205C>T p.R1069* | Nonsense Mutation (SNP) | VAF 47/158 reads (30%) | catalogued as rs368793879; called by muse, mutect2, varscan2
- PIK3R1 | c.1915C>T p.R639* (on ENST00000521381 / NM_181523.3; = p.R369* on NM_181504.4) | Nonsense Mutation (SNP) | VAF 36/88 reads (41%) | catalogued as COSV57126125; called by muse, mutect2, varscan2
- TTN | c.87049G>A p.E29017K (on ENST00000591111; = p.E21593K on NM_003319.4) | Missense Mutation (SNP) | VAF 31/74 reads (42%) | PolyPhen probably damaging (0.994); catalogued as COSV60229470; called by muse, mutect2, varscan2
- AC013489.1 | c.785A>G p.E262G | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- CHRNE | c.1A>C p.M1? | Translation Start Site (SNP) | VAF 10/347 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); called by muse, mutect2
- EYA1 | c.482C>G p.T161R | Missense Mutation (SNP) | VAF 140/249 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.373); called by muse, mutect2, varscan2
- HCAR3 | c.91C>T p.P31S | Missense Mutation (SNP) | VAF 92/271 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- MGAM2 | c.4807G>T p.D1603Y | Missense Mutation (SNP) | VAF 34/300 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- OR2B11 | c.649C>T p.L217F | Missense Mutation (SNP) | VAF 64/147 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRKDC | c.11884C>T p.R3962W | Missense Mutation (SNP) | VAF 38/77 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RNF207 | c.1487G>C p.W496S | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- RTF1 | c.296A>G p.D99G | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- SHISA6 | c.761A>G p.N254S | Missense Mutation (SNP) | VAF 49/124 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.622); called by muse, mutect2
- SLC38A1 | c.1100C>T p.T367I | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SLIT2 | c.3718T>G p.F1240V | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2
- TRUB1 | c.122C>T p.A41V | Missense Mutation (SNP) | VAF 43/59 reads (73%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTN | c.27314G>A p.G9105D (on ENST00000591111; = p.G8178D on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 79/185 reads (43%) | PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- XIRP1 | c.3596G>T p.C1199F | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZNF507 | c.1772T>C p.I591T | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ADAM18 | c.1164A>G p.Q388= | Silent (SNP) | VAF 9/51 reads (18%) | called by muse, mutect2, varscan2
- ARHGAP32 | c.5808A>G p.R1936= (on ENST00000310343 / NM_001378025.1; = p.R1587= on NM_014715.4) | Silent (SNP) | VAF 83/169 reads (49%) | called by muse, mutect2, varscan2
- FGF6 | c.591G>A p.P197= | Silent (SNP) | VAF 56/136 reads (41%) | catalogued as rs776204115; called by muse, mutect2, varscan2
- KRTAP13-2 | c.204G>A p.T68= | Silent (SNP) | VAF 60/109 reads (55%) | catalogued as rs746030923; called by muse, mutect2, varscan2
- NXF1 | c.1473G>C p.L491= | Silent (SNP) | VAF 37/77 reads (48%) | called by muse, mutect2, varscan2
- PKP2 | c.2070C>T p.I690= | Silent (SNP) | VAF 88/241 reads (37%) | catalogued as rs538127756, COSV50755620; called by muse, mutect2, varscan2
- SLC1A7 | c.375G>A p.T125= | Silent (SNP) | VAF 32/235 reads (14%) | catalogued as rs371121273; called by muse, mutect2, varscan2
- SLC4A10 | c.315C>T p.T105= | Silent (SNP) | VAF 59/117 reads (50%) | catalogued as rs374865086; called by muse, mutect2, varscan2
- SYNDIG1L | c.705C>T p.N235= | Silent (SNP) | VAF 108/143 reads (76%) | catalogued as rs764855912, COSV100526538; called by muse, mutect2, varscan2
- TTN | c.13209C>T p.T4403= (on ENST00000591111; = p.T4357= on NM_003319.4) | Silent (SNP) | VAF 41/94 reads (44%) | called by muse, mutect2, varscan2
- DPF3 | chr14:72894105 del AG | 5'Flank (DEL) | VAF 30/47 reads (64%) | catalogued as rs766420993; called by mutect2, varscan2
- EPS8L2 | c.895+72A>C | Intron (SNP) | VAF 8/34 reads (24%) | catalogued as rs753850480; called by muse, mutect2
- FAM183BP | n.459C>T | RNA (SNP) | VAF 29/115 reads (25%) | catalogued as rs777630638; called by muse, mutect2, varscan2
- GALNT9 | c.1077+270G>A | Intron (SNP) | VAF 44/87 reads (51%) | catalogued as rs1429858126; called by muse, mutect2, varscan2
- GPI | c.123-349G>A | Intron (SNP) | VAF 45/259 reads (17%) | called by muse, mutect2, varscan2
